Somatic mutation profile of tumor specimen CPT001846 (aliquot CPT001846-0011) from CPTAC case 01BR044, project CPTAC-2 (Breast — Squamous Cell Neoplasms). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 84.9 years (30,994 days).
Specimen CPT001846: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e10cd04e-8961-4ed1-9f70-7278fb9e91ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT001849 (Blood Derived Normal), aliquot CPT001849-0002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0353beb4-ed42-4a99-ac1d-edfec6b8a4ea

The open-access MAF lists 102 somatic variants for this specimen: 67 protein-altering or splice-affecting, 18 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 18, Intron 7, Nonsense Mutation 5, 3'UTR 4, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 2, 5'UTR 2, 5'Flank 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL3 | c.3964C>T p.Q1322* | Nonsense Mutation (SNP) | VAF 115/297 reads (39%) | catalogued as rs1555743954; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 270/485 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTR3 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs1171340718; called by muse, mutect2, varscan2
- ANKRD33B | c.1025T>G p.V342G | Missense Mutation (SNP) | VAF 124/195 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56979659; called by muse, mutect2, varscan2
- C1QL2 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV55605834, COSV55606671; called by muse, mutect2, varscan2
- CBLL2 | c.1100A>T p.Q367L | Missense Mutation (SNP) | VAF 138/316 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs140922897; called by muse, mutect2, varscan2
- CDH26 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as rs766848205, COSV54844761; called by muse, mutect2, varscan2
- COG7 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 61/355 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs764545607, COSV56150354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBP1 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 26/131 reads (20%) | catalogued as rs768207214; called by muse, mutect2, varscan2
- GLI3 | c.1397A>G p.D466G | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV67888649; called by mutect2, varscan2
- MRGPRX1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 50/411 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs757667446; called by muse, mutect2, varscan2
- MYO9B | c.3616G>A p.V1206I | Missense Mutation (SNP) | VAF 44/447 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs569931532; called by muse, mutect2, varscan2
- PKHD1L1 | c.7858G>A p.G2620S | Missense Mutation (SNP) | VAF 69/369 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101005308, COSV65738804; called by muse, mutect2, varscan2
- PROB1 | c.3035T>C p.L1012S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as COSV100130151; called by muse, mutect2, varscan2
- PSD4 | c.2388G>A p.T796= | Splice Region (SNP) | VAF 42/317 reads (13%) | catalogued as rs368488108, COSV55529435; called by muse, mutect2, varscan2
- RBM7 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV64955591, COSV64955880; called by muse, mutect2, varscan2
- SMPD1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 63/425 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as rs753287070; called by muse, mutect2, varscan2
- SMPDL3B | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746544808; called by muse, mutect2, varscan2
- SPRR1B | c.40C>G p.P14A | Missense Mutation (SNP) | VAF 114/282 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs770728317, COSV61067745; called by muse, mutect2, varscan2
- TPSG1 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.332); catalogued as rs775093652; called by muse, mutect2, varscan2
- UNC13A | c.5105C>T p.A1702V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); catalogued as rs771677125, COSV53213027; called by mutect2, varscan2
- ZNF442 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as rs1289517870; called by muse, mutect2
- ABCA13 | c.3578C>G p.S1193C | Missense Mutation (SNP) | VAF 182/452 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADAMTS12 | c.2902A>C p.S968R | Missense Mutation (SNP) | VAF 34/594 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2
- ARHGAP10 | c.1595C>A p.A532E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2
- ATRN | c.579_582del p.I194Mfs*4 | Frame Shift Del (DEL) | VAF 42/142 reads (30%) | called by mutect2, pindel, varscan2
- BICD1 | c.2130G>C p.K710N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- BTBD3 | c.1369T>G p.Y457D | Missense Mutation (SNP) | VAF 25/438 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.216); called by muse, mutect2
- C10orf71 | c.1175_1178del p.E392Vfs*6 | Frame Shift Del (DEL) | VAF 33/146 reads (23%) | called by pindel, varscan2
- CFAP44 | c.875_881dup p.H295Ifs*32 | Frame Shift Ins (INS) | VAF 12/98 reads (12%) | called by mutect2, varscan2
- CHM | c.881T>C p.M294T | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CILP | c.1372T>C p.S458P | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.578); called by muse, mutect2
- CNTRL | c.5581+1G>C p.X1861_splice | Splice Site (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- CT47B1 | c.38A>G p.D13G | Missense Mutation (SNP) | VAF 76/306 reads (25%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CYP21A2 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 138/836 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- DDX42 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- DOCK10 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELF1 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 51/322 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ELF1 | c.1539G>C p.Q513H | Missense Mutation (SNP) | VAF 72/451 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- F11 | c.997A>T p.T333S | Missense Mutation (SNP) | VAF 109/457 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRY | c.8342_8366del p.E2781Gfs*24 | Frame Shift Del (DEL) | VAF 49/293 reads (17%) | called by mutect2, pindel, varscan2
- IKZF4 | c.744C>G p.Y248* | Nonsense Mutation (SNP) | VAF 36/112 reads (32%) | called by muse, mutect2, varscan2
- IRS1 | c.1135dup p.A379Gfs*18 | Frame Shift Ins (INS) | VAF 66/138 reads (48%) | called by mutect2, pindel, varscan2
- LCOR | c.4022A>T p.E1341V | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- LDLRAP1 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 71/373 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- LGALS1 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MMP16 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- MUC16 | c.10957A>C p.K3653Q | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYH15 | c.3121C>A p.Q1041K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- NEK10 | c.1345A>G p.M449V | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- NPPB | c.86T>A p.L29Q | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NPY1R | c.53T>C p.F18S | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSBP | c.1312-1G>A p.X438_splice | Splice Site (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- PEAK1 | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 123/254 reads (48%) | called by muse, mutect2, varscan2
- PLRG1 | c.1431A>C p.L477F | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- POPDC3 | c.838C>A p.Q280K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- POU5F1B | c.955T>G p.F319V | Missense Mutation (SNP) | VAF 73/550 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- REG3A | c.520A>T p.T174S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- RELB | c.356C>A p.P119Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SMARCD3 | c.968C>T p.S323F (on ENST00000262188 / NM_001003801.2; = p.S310F on NM_003078.4) | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- SORT1 | c.490A>T p.T164S | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SRGAP1 | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); called by muse, mutect2
- STAG2 | c.1821+2T>A p.X607_splice | Splice Site (SNP) | VAF 36/74 reads (49%) | called by muse, mutect2, varscan2
- TRIM51GP | c.669G>T p.R223S | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UBAP2 | c.3184C>G p.P1062A | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP28 | c.1490A>G p.Y497C | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ASXL3 | c.3963G>A p.K1321= | Silent (SNP) | VAF 116/296 reads (39%) | called by muse, mutect2, varscan2
- C1QTNF4 | c.258G>A p.P86= | Silent (SNP) | VAF 77/422 reads (18%) | called by muse, mutect2, varscan2
- COASY | c.846G>A p.L282= | Silent (SNP) | VAF 66/393 reads (17%) | called by muse, mutect2, varscan2
- CYP17A1 | c.379C>T p.L127= | Silent (SNP) | VAF 29/443 reads (7%) | catalogued as rs1234235286; called by muse, mutect2
- DDX59 | c.1386A>G p.E462= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1158081254; called by muse, mutect2, varscan2
- DNAH10 | c.7866C>T p.S2622= (on ENST00000409039; = p.S2561= on NM_207437.3) | Silent (SNP) | VAF 56/233 reads (24%) | called by muse, mutect2, varscan2
- EPB41L1 | c.2484C>T p.I828= | Silent (SNP) | VAF 68/450 reads (15%) | catalogued as COSV52435930; called by muse, mutect2, varscan2
- HNRNPR | c.927G>C p.L309= | Silent (SNP) | VAF 80/345 reads (23%) | called by muse, mutect2, varscan2
- KCNMB2 | c.267G>A p.A89= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as rs754356731, COSV100844016, COSV64200769; called by muse, mutect2, varscan2
- LRRC41 | c.1710G>T p.G570= | Silent (SNP) | VAF 69/361 reads (19%) | catalogued as COSV58442401; called by muse, mutect2, varscan2
- OTUD7A | c.1512G>A p.E504= (on ENST00000307050 / NM_001382637.1; = p.E497= on NM_130901.3) | Silent (SNP) | VAF 115/433 reads (27%) | catalogued as rs768716767; called by muse, mutect2, varscan2
- PLCB1 | c.840C>T p.P280= | Silent (SNP) | VAF 44/136 reads (32%) | called by muse, mutect2, varscan2
- RIN3 | c.2937G>A p.V979= | Silent (SNP) | VAF 66/281 reads (23%) | catalogued as rs894163402; called by muse, mutect2, varscan2
- RXFP2 | c.1212C>T p.D404= | Silent (SNP) | VAF 85/366 reads (23%) | catalogued as rs773336556; called by muse, mutect2, varscan2
- SALL3 | c.1728C>T p.G576= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs761787389, COSV73306160; called by muse, mutect2, varscan2
- SCN4A | c.4602G>A p.T1534= | Silent (SNP) | VAF 59/304 reads (19%) | catalogued as rs186181122, COSV71127773; called by muse, mutect2, varscan2
- SYT9 | c.1089T>C p.L363= | Silent (SNP) | VAF 30/278 reads (11%) | called by muse, mutect2, varscan2
- ZNF578 | c.1392C>T p.F464= | Silent (SNP) | VAF 15/286 reads (5%) | catalogued as COSV69736340; called by muse, mutect2
- CHMP4B | c.*12G>T | 3'UTR (SNP) | VAF 73/438 reads (17%) | catalogued as COSV54136163; called by muse, mutect2, varscan2
- CORIN | c.-17del | 5'UTR (DEL) | VAF 38/134 reads (28%) | called by mutect2, pindel, varscan2
- EZH1 | c.-113C>G | 5'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- FAM20A | c.*1187C>A | 3'UTR (SNP) | VAF 62/302 reads (21%) | called by muse, mutect2, varscan2
- GFOD1 | c.*3985C>A | 3'UTR (SNP) | VAF 26/362 reads (7%) | called by muse, mutect2
- HDAC5 | chr17:44078293 G>A | 3'Flank (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- PIK3CD | c.-138+2449G>T | Intron (SNP) | VAF 169/740 reads (23%) | called by muse, mutect2, varscan2
- PINLYP | c.481+41G>C | Intron (SNP) | VAF 10/151 reads (7%) | catalogued as rs1041464439; called by muse, mutect2
- PMF1 | c.162-6694G>C | Intron (SNP) | VAF 41/187 reads (22%) | called by muse, mutect2, varscan2
- POTEG | c.811-1124_811-1123insATTTT | Intron (INS) | VAF 16/147 reads (11%) | called by mutect2, varscan2*
- PRRG1 | c.172-12299C>T | Intron (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158661 C>T | 5'Flank (SNP) | VAF 32/139 reads (23%) | catalogued as rs957045295; called by muse, mutect2, varscan2
- SEC63 | c.124+1781G>A | Intron (SNP) | VAF 12/22 reads (55%) | catalogued as rs961762163, COSV64598444; called by muse, mutect2, varscan2
- SLCO4A1 | chr20:62642024 A>G | 5'Flank (SNP) | VAF 7/19 reads (37%) | catalogued as rs1322385841; called by muse, mutect2, varscan2
- TACC2 | c.*102G>A | 3'UTR (SNP) | VAF 84/161 reads (52%) | catalogued as rs569504865; called by muse, mutect2, varscan2
- TBC1D3P2 | n.356G>T | RNA (SNP) | VAF 126/607 reads (21%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+3710T>C | Intron (SNP) | VAF 51/501 reads (10%) | called by muse, mutect2, varscan2
